Somatic mutation profile of tumor specimen MP2PRT-PAVNBN-TMP1-A (aliquot MP2PRT-PAVNBN-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVNBN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,592 days).
Specimen MP2PRT-PAVNBN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 216c3148-6153-4b24-8520-a046d190cda6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNBN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNBN-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc97b280-5f59-46ba-a294-2eb588fb6ad1

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD3C | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535257873; called by muse, mutect2, varscan2
- PCDH9 | c.3578A>G p.N1193S (on ENST00000377865 / NM_203487.3; = p.N1159S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6D | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 55/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TMEM63B | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIF7 | c.2376G>A p.A792= | Silent (SNP) | VAF 62/310 reads (20%) | catalogued as rs749654275; called by muse, mutect2, varscan2
- STAT4 | c.246T>C p.N82= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs1481226892; called by muse, mutect2, varscan2
- TBKBP1 | c.1404C>T p.G468= | Silent (SNP) | VAF 73/464 reads (16%) | catalogued as rs762463634; called by muse, varscan2
- ZDHHC23 | c.354C>G p.T118= | Silent (SNP) | VAF 40/255 reads (16%) | catalogued as COSV100362021; called by muse, mutect2, varscan2
- FICD | c.302-213G>A | Intron (SNP) | VAF 48/297 reads (16%) | catalogued as rs540987541; called by muse, varscan2
